Surgical pathology report (de-identified scan), TCGA case TCGA-SN-A84X, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site BLN - Baylor, specimen TCGA-SN-A84X-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Accession #:

Collected:

Received:

PATHOLOGIC DIAGNOSIS

TESTICLE, RIGHT, RADICAL ORCHIECTOMY:

- MIXED GERM CELL TUMOR
- EMBRYONAL CARCINOMA 15%, YOLK SAC TUMOR 5%, MATURE TERATOMA 30%, IMMATURE TERATOMA 30%, SEMINOMA 20%
- 15 CM IN THE LARGEST DIMENSION
- TUMOR NECROSIS 20%
- NO INVASION INTO TUNICA VAGINALIS
- QUESTIONABLE VASCULAR INVASION
- MARGINS FREE

College of American Pathologists Synoptic Report:

Procedure: Radical orchiectomy Preoperative
serum tumor markers

Specimen laterality: Right HCG: 74 mIU/mL

Tumor focality: Unifocal AFP: 45 ng/mL

Tumor size: 15.0 x 11.0 x 10.0 cm LDH: 432 U/L

Macroscopic extent of tumor: Confined to the testis

Histological type: Teratoma, immature

Margins: Free

Lymphovascular invasion: Questionable vascular invasion

Tumor size (cm): 15 cm in the largest dimension

Primary tumor (T): pT2

Serum tumor markers (S): pS2

Lymph node (N): pNX

Distant metastasis (M): pMX

Stage grouping: Stage IB

Site of distant metastasis: Not known

Surgical margins: Free

Comment: The finding was communicated via secure email with
on

and

Staff Pathologist

Pertinent Clinical Information

-year-old Hispanic male with right testicular mass.

ICD-O-3
Mixed germ cell tumor 9085/3
Site B Testis NOS C62.9
Testicle NOS C62.9
9/20/12/1/3

[page 2 of 3]
Gross Description

Specimen Material: Right testicular mass

Received fresh labeled "RIGHT TESTICULAR MASS" is a right testicular mass (fixed 748 grams), 15 x 11 x 10 cm with attached spermatic cord (7 cm length x 3 cm diameter).

The surface is inked blue. The specimen is bivalved to show the testicular parenchyma completely replaced by a tan-yellow to tan-white, variegated tumor. Sectioning through the spermatic cord and adjacent soft tissue showed the actual cord measures 0.4 cm in diameter and displays a pinpoint lumen. A possible thrombosed vein is identified within the adjacent soft tissue. The tumor appears confined to the testis. The epididymis is not identified.

Representative sections are submitted as follows:

- 1 spermatic cord margin, en face
- 2 mid spermatic cord with adjacent soft tissue
- 3 spermatic cord near testis with adjacent soft tissue
- 4-15 tumor (possible normal testis in A8-9)

Pathology Resident

Microscopic Description

CD117 highlights the seminomatous component.

Consult: concurs

The staff pathologist listed below has reviewed this case.

Pathology Resident

Electronically Signed Out

Staff Pathologist

Per TSS, dx discrepancy from states
TCGA tumor to be: embryonal 15%, yolk sac 5%,
mature teratoma 30%, Immature Teratoma 30%,
Seminoma 20%

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form 4.05 ☒

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Testicular Germ Cell Tumors - (Testicular Germ Cell Tumors)	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report EMBRYONAL CARCINOMA 15%, YOLK SAC TUMOR 5%, MATURE TERATOMA 30%, IMMATURE TERATOMA 30%, SEMINOMA 20% **Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.**

Histologic features of the sample provided for TCGA, as reflected on the CQCF YOLK SAC TUMOR 10%, MATURE TERATOMA 50%, SEMINOMA 40%

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

The tissue collected for research was taken from an area that was not representative of the entire specimen.

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file 6ed4f17e-a078-412a-a11d-ce598cff2da4 (TCGA-SN-A84X.13BE8705-5E39-4A38-A766-4E28DCEC4B4A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).